Somatic mutation profile of tumor specimen TCGA-CR-7386-01A (aliquot TCGA-CR-7386-01A-11D-2012-08) from TCGA case TCGA-CR-7386, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 69.1 years (25,238 days).
Specimen TCGA-CR-7386-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27d61afa-1403-4a04-bb06-49d38d679de0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7386-10A (Blood Derived Normal), aliquot TCGA-CR-7386-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/859de131-2bfc-4acf-9a8a-eda4cbb54764

The open-access MAF lists 192 somatic variants for this specimen: 137 protein-altering or splice-affecting, 49 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 49, Nonsense Mutation 11, Intron 4, Frame Shift Ins 2, RNA 1, Splice Site 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.330G>A p.W110* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | hotspot (GDC flag); catalogued as rs121913389, CM060208, COSV58682827, COSV58708986; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 18/142 reads (13%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- RBM39 | c.1058C>T p.T353I | Missense Mutation (SNP) | VAF 10/84 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV53614904; called by muse, mutect2
- ABCG4 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100266644, COSV56644989, COSV56645081; called by muse, mutect2, varscan2
- ADGRE2 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV100215856; called by muse, mutect2, varscan2
- AKAP11 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV99078672, COSV99213699; called by muse, mutect2, varscan2
- ANGPTL6 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.986); catalogued as COSV99463480; called by muse, mutect2, varscan2
- ANK2 | c.639G>C p.Q213H | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100000644; called by muse, mutect2
- AOX1 | c.3949G>A p.D1317N | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99613494; called by muse, mutect2, varscan2
- APOA5 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99911240; called by muse, mutect2, varscan2
- ASB2 | c.526C>G p.L176V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100279277; called by muse, mutect2
- ASXL3 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.492); catalogued as rs1469589041, COSV99322809, COSV99324121; called by muse, mutect2, varscan2
- ATP7A | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 77/252 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.044); catalogued as COSV100430545; called by muse, mutect2, varscan2
- ATR | c.182C>G p.S61C | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV100637926, COSV63392658; called by muse, mutect2, varscan2
- BTBD16 | c.1458G>C p.L486F | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.509); catalogued as COSV99584632; called by muse, mutect2, varscan2
- CCDC144A | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 77/297 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV100501991; called by muse, mutect2, varscan2
- CCDC146 | c.2860G>C p.E954Q | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99592379; called by muse, mutect2
- CCDC88A | c.3217G>C p.E1073Q | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV99710076; called by muse, mutect2
- CCR6 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.36); catalogued as COSV100550997; called by muse, mutect2
- CDC42BPA | c.2416G>T p.D806Y | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); catalogued as COSV100504318; called by muse, mutect2, varscan2
- CDH24 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.986); catalogued as COSV99399344; called by muse, mutect2, varscan2
- CELSR2 | c.8137C>A p.Q2713K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as COSV99603433; called by muse, mutect2, varscan2
- CHRNG | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99285632; called by muse, mutect2, varscan2
- CNTNAP2 | c.2816C>T p.S939F | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100664509, COSV100673820; called by muse, mutect2, varscan2
- COL17A1 | c.1730G>C p.S577T | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.098); catalogued as COSV100793105; called by muse, mutect2
- CSHL1 | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as COSV99367869; called by muse, mutect2
- CTSF | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs771743743, COSV100074200; called by muse, mutect2
- CUBN | c.555G>C p.Q185H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV100910559; called by muse, mutect2, varscan2
- CYP2B6 | c.1408C>G p.L470V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.556); catalogued as COSV100137414; called by muse, mutect2, varscan2
- DNAH5 | c.5389C>G p.Q1797E | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV54242295, COSV99444479; called by muse, mutect2, varscan2
- DNAH5 | c.2999C>T p.S1000F | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as COSV99447412; called by muse, mutect2, varscan2
- DOP1A | c.233G>C p.G78A | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99381436; called by muse, mutect2, varscan2
- DPP3 | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as rs199617262, COSV100855528; called by muse, mutect2, varscan2
- ELAPOR1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752456350, COSV64046269; called by muse, mutect2, varscan2
- ENPEP | c.26C>G p.S9C | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.436); catalogued as rs147278588, COSV99487523; called by muse, mutect2, varscan2
- EPHB1 | c.1929G>C p.K643N | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67656588; called by muse, mutect2, varscan2
- ESYT3 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 49/442 reads (11%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.996); catalogued as rs1560239378, COSV101272644; called by muse, mutect2, varscan2
- FAM13A | c.2844-1G>C p.X948_splice | Splice Site (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99983211; called by muse, mutect2, varscan2
- FAM3A | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100453597; called by muse, mutect2, varscan2
- FAT1 | c.9803C>G p.S3268* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV71672462; called by muse, mutect2, varscan2
- FAT1 | c.8513C>G p.S2838* | Nonsense Mutation (SNP) | VAF 15/127 reads (12%) | catalogued as COSV101499686, COSV71672363, COSV99081604; called by muse, mutect2, varscan2
- FAT1 | c.1798C>T p.Q600* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV71671806; called by muse, mutect2, varscan2
- FBN3 | c.7985C>T p.P2662L | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs1363472567, COSV54470096; called by muse, mutect2, varscan2
- FLG | c.3104C>G p.S1035C | Missense Mutation (SNP) | VAF 44/752 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100910478, COSV100911331; called by muse, mutect2
- GCNT2 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101097329; called by muse, mutect2, varscan2
- GLRB | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1560962621, COSV52412316; called by muse, mutect2, varscan2
- GNAS | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); catalogued as rs773990885, COSV100005946; called by muse, mutect2, varscan2
- GPC6 | c.1001C>A p.S334Y | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100988298; called by muse, mutect2, varscan2
- GRID1 | c.1360G>C p.E454Q | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100023070; called by muse, mutect2
- GRIP1 | c.2243C>A p.T748N (on ENST00000359742 / NM_001379345.1; = p.T696N on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV99668771; called by muse, mutect2
- GRM3 | c.2046C>A p.F682L | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.95); catalogued as COSV64478679, COSV64480448; called by muse, mutect2, varscan2
- GUF1 | c.2003C>G p.S668C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV99776862; called by muse, mutect2, varscan2
- HECW1 | c.3307C>G p.R1103G | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV101223143; called by muse, mutect2, varscan2
- HS3ST6 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99036586, COSV99562653; called by muse, mutect2, varscan2
- HSP90AA1 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53490338, COSV99355157; called by muse, mutect2, varscan2
- HSPG2 | c.8474G>A p.G2825E | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV101020547; called by muse, mutect2, varscan2
- IQCG | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 28/225 reads (12%) | catalogued as COSV99502210; called by muse, mutect2, varscan2
- JCAD | c.1972G>C p.D658H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.875); catalogued as COSV100948235; called by muse, mutect2, varscan2
- KATNIP | c.1915G>C p.E639Q | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.714); catalogued as COSV99850494; called by muse, mutect2, varscan2
- KIAA1755 | c.1144G>C p.D382H | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1568762947, COSV99641735; called by muse, mutect2
- KIAA2026 | c.4208C>G p.S1403C | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV101198942, COSV67353223; called by muse, mutect2, varscan2
- KLHL20 | c.1575G>C p.E525D | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99268262; called by muse, mutect2
- LAMC1 | c.3987G>C p.K1329N | Missense Mutation (SNP) | VAF 35/229 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.383); catalogued as COSV99279301; called by muse, mutect2, varscan2
- LAMC1 | c.4414G>C p.E1472Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.617); catalogued as COSV99279304; called by muse, mutect2, varscan2
- LCN6 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV100366423; called by muse, mutect2, varscan2
- LRIG2 | c.2176C>T p.R726C | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1460137687, COSV100743166; called by muse, mutect2, varscan2
- MALT1 | c.1484G>C p.G495A | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); catalogued as COSV100618647; called by muse, mutect2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2
- MDC1 | c.5228C>G p.S1743C | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as COSV100902696; called by muse, mutect2, varscan2
- MED13L | c.3420C>G p.I1140M | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV99928345; called by muse, mutect2, varscan2
- MEPE | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.31); catalogued as COSV100734917; called by muse, mutect2, varscan2
- MFSD8 | c.1337G>T p.G446V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99614270; called by muse, mutect2, varscan2
- MYH9 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53382462, COSV53382648; called by muse, mutect2, varscan2
- NBPF26 | c.2153C>T p.S718L (on ENST00000620612; = p.S456L on NM_001351372.1) | Missense Mutation (SNP) | VAF 11/391 reads (3%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.519); catalogued as rs1553271731; called by muse, mutect2
- NIPA2 | c.328C>T p.L110F | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as COSV100508796; called by muse, mutect2
- NLRP7 | c.1498G>A p.V500I | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV60171302; called by muse, mutect2, varscan2
- OBI1 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs752393396, COSV99932362; called by muse, mutect2, varscan2
- OR2J3 | c.76C>G p.L26V | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as COSV101013597; called by muse, mutect2, varscan2
- OR52E2 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100384740, COSV58613001; called by muse, mutect2
- OR56A1 | c.72G>C p.Q24H | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.764); catalogued as COSV100360430; called by muse, mutect2
- OR8B4 | c.29C>T p.T10I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as COSV100635780; called by muse, mutect2, varscan2
- PAK5 | c.2050G>C p.E684Q | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV100781221, COSV62030929; called by muse, mutect2, varscan2
- PCBP2 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 19/231 reads (8%) | catalogued as COSV100827530; called by muse, mutect2
- PCDH17 | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs1364348588, COSV64971600; called by muse, mutect2, varscan2
- PCDHA2 | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.349); catalogued as COSV100973733, COSV65371932; called by muse, mutect2, varscan2
- PCDHGB2 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.578); catalogued as COSV99534331; called by muse, mutect2, varscan2
- PEA15 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1250341559, COSV58785540; called by muse, mutect2, varscan2
- PIWIL2 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs756790734, COSV63250433; called by muse, varscan2
- PLAT | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV54274748; called by muse, mutect2, varscan2
- PMCH | c.185C>A p.S62Y | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.259); catalogued as COSV100268208; called by mutect2, varscan2
- POU2F2 | c.695A>G p.Y232C (on ENST00000526816 / NM_001207025.3; = p.Y216C on NM_002698.5) | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1412192614, COSV100657300; called by muse, mutect2, varscan2
- PPM1A | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV100348904; called by muse, mutect2
- PRG4 | c.2261C>G p.P754R | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV100798150; called by muse, mutect2, varscan2
- PRKDC | c.1927G>T p.E643* | Nonsense Mutation (SNP) | VAF 6/96 reads (6%) | catalogued as COSV100039427; called by muse, mutect2
- PSORS1C2 | c.41G>T p.C14F | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV99456036; called by mutect2, varscan2
- PTPRB | c.5248G>C p.D1750H | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54252071, COSV99716597; called by muse, mutect2
- RAD50 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs763432574, COSV54753694; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RARS2 | c.587C>G p.S196C | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.684); catalogued as COSV101057143; called by muse, mutect2, varscan2
- RBM28 | c.1423C>G p.Q475E | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.182); catalogued as COSV56163825, COSV99775948; called by muse, mutect2, varscan2
- REV3L | c.3430G>A p.E1144K | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100725050; called by muse, mutect2, varscan2
- RGS20 | c.946G>A p.E316K (on ENST00000297313 / NM_170587.4; = p.E169K on NM_003702.4) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99391963; called by muse, mutect2, varscan2
- RTP1 | c.495C>G p.C165W | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100398694; called by muse, mutect2, varscan2
- RUFY3 | c.249G>C p.L83F | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99887104; called by muse, mutect2, varscan2
- RYR3 | c.12886G>A p.E4296K (on ENST00000389232; = p.E4297K on NM_001036.6) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as COSV101212324; called by muse, mutect2, varscan2
- SELENOP | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101539865; called by muse, mutect2, varscan2
- SF3B2 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100488360; called by muse, mutect2, varscan2
- SH3BP4 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs759476176, COSV100749078; called by muse, mutect2, varscan2
- SH3PXD2A | c.2075C>G p.S692* (on ENST00000369774 / NM_001365079.1; = p.S664* on NM_014631.2) | Nonsense Mutation (SNP) | VAF 25/175 reads (14%) | catalogued as COSV100279984; called by muse, mutect2, varscan2
- SHROOM4 | c.1217C>G p.T406R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV99173183; called by muse, mutect2
- SON | c.1579C>T p.H527Y | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.34); catalogued as rs1002617293, COSV99277464; called by muse, mutect2, varscan2
- SRCAP | c.7885G>A p.E2629K | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.021); catalogued as rs1292951839, COSV52674100; called by muse, mutect2, varscan2
- STK32A | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV100096858; called by muse, mutect2
- SYNE1 | c.20251G>C p.D6751H (on ENST00000367255 / NM_182961.4; = p.D6680H on NM_033071.3) | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV99558297; called by muse, mutect2
- TACSTD2 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM074587, COSV100973734; called by muse, mutect2, varscan2
- TCF4 | c.955C>A p.Q319K | Missense Mutation (SNP) | VAF 47/298 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV100610014; called by muse, mutect2, varscan2
- TICRR | c.3966G>C p.K1322N | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.282); catalogued as COSV99176129; called by muse, mutect2
- TIGAR | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1383325573, COSV51630417; called by muse, mutect2, varscan2
- TLN1 | c.7452G>C p.E2484D | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV100147532; called by muse, mutect2, varscan2
- TMEM178A | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.552); catalogued as rs868530808, COSV99931705, COSV99931835; called by muse, mutect2
- TNN | c.3271G>A p.D1091N | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as rs1412346099, COSV53426041; called by muse, mutect2, varscan2
- TOGARAM1 | c.881C>G p.S294C | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100753045; called by muse, mutect2, varscan2
- TOPBP1 | c.1364C>G p.S455* | Nonsense Mutation (SNP) | VAF 36/171 reads (21%) | catalogued as COSV99605109; called by muse, mutect2, varscan2
- TRIM68 | c.815C>G p.S272C | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100331674, COSV56168416; called by muse, mutect2, varscan2
- TRPM4 | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs748513383, COSV99419411; called by muse, mutect2, varscan2
- TTC17 | c.2170G>C p.E724Q | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.046); catalogued as COSV50008402; called by muse, mutect2
- TTC3 | c.2588G>C p.R863T | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.156); catalogued as COSV100695256, COSV61287246, COSV61292926; called by muse, mutect2, varscan2
- TTC33 | c.44C>G p.S15* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV100531851, COSV100532132; called by muse, mutect2, varscan2
- UNC80 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.189); catalogued as rs756423127, COSV55888950, COSV99778961; called by muse, mutect2, varscan2
- WIPF1 | c.1276G>C p.G426R | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99768333; called by muse, mutect2, varscan2
- XK | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101064592, COSV66120940; called by muse, mutect2, varscan2
- XKR8 | c.1108C>A p.Q370K | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.043); catalogued as COSV100871906, COSV100872179; called by muse, mutect2, varscan2
- ZNF417 | c.979A>G p.R327G | Missense Mutation (SNP) | VAF 12/293 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1419262933, COSV100364147; called by muse, mutect2
- ZNF599 | c.550C>G p.Q184E | Missense Mutation (SNP) | VAF 6/143 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV100251063; called by muse, mutect2
- APPL2 | c.1939_1940dup p.D648Qfs*36 | Frame Shift Ins (INS) | VAF 5/49 reads (10%) | called by pindel, varscan2
- AREG | c.698G>C p.G233A | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- PCDHA13 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- TP53 | c.631_632del p.T211Ffs*4 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | called by pindel, varscan2
- AFF2 | c.3519G>A p.L1173= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV99662890; called by muse, mutect2, varscan2
- ATR | c.4233C>T p.S1411= | Silent (SNP) | VAF 43/168 reads (26%) | catalogued as COSV100637925; called by muse, mutect2, varscan2
- ATXN2 | c.1605C>T p.F535= (on ENST00000550104; = p.F375= on NM_002973.4) | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV66483094; called by muse, mutect2, varscan2
- BAHCC1 | c.6195G>A p.P2065= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs562201041; called by muse, mutect2
- BTF3 | c.429G>C p.L143= (on ENST00000380591 / NM_001037637.1; = p.L99= on NM_001207.4) | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV100246663; called by muse, mutect2, varscan2
- C3 | c.2497C>T p.L833= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV99836369; called by muse, mutect2
- CFAP69 | c.2716C>T p.L906= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV100289943; called by muse, mutect2
- CNTNAP2 | c.237C>T p.S79= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs145162968, COSV62274517; ClinVar: uncertain significance / likely benign / benign; called by muse, mutect2, varscan2
- COL16A1 | c.237G>A p.L79= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as COSV54701465, COSV99593953; called by muse, mutect2, varscan2
- CST9 | c.69C>G p.L23= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as rs375634749; called by muse, mutect2
- DCAF8L1 | c.141G>C p.S47= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV101491428, COSV101491459; called by muse, mutect2, varscan2
- DGKG | c.2163C>T p.T721= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs137961016; called by muse, mutect2, varscan2
- DGKQ | c.1740G>A p.A580= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs368255631, COSV53280318; called by muse, mutect2, varscan2
- DNAJC11 | c.231C>T p.I77= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV99602018; called by muse, mutect2, varscan2
- DST | c.17844C>T p.I5948= (on ENST00000361203 / NM_001374722.1; = p.I3645= on NM_015548.5) | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV99752215; called by muse, mutect2
- DUSP8 | c.729C>T p.I243= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs753062218, COSV59031695; called by muse, mutect2, varscan2
- DYNC1H1 | c.6066C>T p.Y2022= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs769412278, COSV100794680; called by muse, mutect2, varscan2
- ELOF1 | c.84C>T p.F28= | Silent (SNP) | VAF 15/138 reads (11%) | catalogued as COSV99370614; called by muse, mutect2, varscan2
- FETUB | c.27C>A p.L9= | Silent (SNP) | VAF 83/302 reads (27%) | catalogued as COSV99408935; called by muse, mutect2, varscan2
- GALNT3 | c.1188C>T p.F396= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV101204893; called by muse, mutect2, varscan2
- HAS2 | c.1584G>A p.T528= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as rs763025947, COSV100391600; called by muse, mutect2, varscan2
- HBP1 | c.417C>T p.I139= | Silent (SNP) | VAF 19/170 reads (11%) | catalogued as COSV99753117; called by muse, mutect2, varscan2
- HSD17B4 | c.972G>C p.L324= (on ENST00000414835 / NM_001199291.3; = p.L299= on NM_000414.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/133 reads (7%) | catalogued as COSV99819655; called by muse, mutect2
- INAVA | c.1554G>A p.P518= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs767472038, COSV100949934; called by muse, mutect2
- INPP5B | c.1767C>T p.D589= (on ENST00000373023; = p.D509= on NM_005540.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as rs765611992, COSV65961301; called by muse, mutect2, varscan2
- IPO13 | c.948C>T p.G316= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV64894793; called by muse, mutect2, varscan2
- ITPRID1 | c.2316G>A p.L772= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV60072824; called by muse, mutect2, varscan2
- KIAA1958 | c.1956C>T p.F652= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100515953; called by muse, mutect2, varscan2
- KRT13 | c.658C>T p.L220= | Silent (SNP) | VAF 21/137 reads (15%) | catalogued as COSV55838929; called by muse, mutect2, varscan2
- LRP2 | c.3372G>A p.K1124= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as rs865909061, COSV55558762, COSV99787367; called by muse, mutect2, varscan2
- MID2 | c.1671G>A p.E557= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV53307202, COSV99464315; called by muse, mutect2, varscan2
- MUTYH | c.1203C>T p.F401= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV58343631; called by muse, mutect2, varscan2
- MYH7 | c.1575G>A p.E525= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV100805882; called by muse, mutect2, varscan2
- PAPPA2 | c.4626C>T p.L1542= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV100867750, COSV62813842; called by muse, mutect2, varscan2
- PCDHGB5 | c.1791C>T p.N597= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs1163309827; called by muse, mutect2, varscan2
- PLCH1 | c.3514C>T p.L1172= (on ENST00000340059 / NM_001130960.2; = p.L1164= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV100396126, COSV58212282; called by muse, mutect2, varscan2
- PYGM | c.1050G>C p.L350= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV99376903; called by muse, mutect2
- REEP5 | c.174C>G p.L58= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV99809605; called by muse, mutect2, varscan2
- RUNX1T1 | c.1731G>A p.G577= (on ENST00000265814 / NM_001198628.1; = p.G550= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99750611; called by muse, mutect2, varscan2
- SEMA6D | c.846G>C p.L282= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV100316706, COSV60373112; called by muse, mutect2, varscan2
- ST6GAL1 | c.1170C>T p.I390= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as COSV99398491; called by muse, mutect2
- STK39 | c.390C>T p.V130= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs1156653117, COSV100596425; called by muse, mutect2, varscan2
- THAP9 | c.1419G>C p.L473= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as COSV100155787, COSV56356083; called by muse, mutect2, varscan2
- TK2 | c.225G>A p.L75= (on ENST00000299697; = p.L131= on NM_004614.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV100228074; called by muse, mutect2, varscan2
- TNIP3 | c.654A>G p.R218= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV99284395; called by muse, mutect2
- ZBTB17 | c.333C>G p.L111= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs779671717, COSV100998990; called by muse, mutect2, varscan2
- ZFHX3 | c.2781G>A p.L927= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV99196354; called by muse, mutect2, varscan2
- ZGLP1 | c.711C>T p.Y237= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs774984645, COSV67059679; called by muse, mutect2, varscan2
- ZNF423 | c.324C>T p.L108= (on ENST00000563137 / NM_001379286.1; = p.L100= on NM_015069.4) | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs1448166273, COSV99280815; called by muse, mutect2, varscan2
- ANKRD33 | c.665-14C>A | Intron (SNP) | VAF 14/80 reads (18%) | catalogued as COSV100001195; called by muse, mutect2, varscan2
- CD300LD | c.40+110C>T | Intron (SNP) | VAF 22/171 reads (13%) | catalogued as COSV100032364; called by muse, mutect2, varscan2
- DLGAP1 | c.1592-14860G>A | Intron (SNP) | VAF 8/59 reads (14%) | catalogued as rs868475732, COSV100229136; called by muse, mutect2, varscan2
- LINC02877 | n.285C>G | RNA (SNP) | VAF 18/284 reads (6%) | called by muse, mutect2
- P4HA1 | c.1148+1082G>C | Intron (SNP) | VAF 34/299 reads (11%) | catalogued as COSV99696747; called by muse, mutect2, varscan2
- TULP4 | c.*2G>A | 3'UTR (SNP) | VAF 11/60 reads (18%) | catalogued as COSV100893349; called by muse, mutect2, varscan2
